Surgical pathology report (de-identified scan), TCGA case TCGA-77-8133, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8133-01A (Primary Tumor).

[page 1 of 2]
Collected

Histopathology Report

RIGHT MIDDLE AND LOWER LOBES, NO. 7 NODE

Clinical Notes:

Ca RLL.

Two specimens submitted:

1: RIGHT MIDDLE AND LOWER LOBES

Macroscopy:

The specimen is labelled "right middle and lower lobes (lung)" and consists of the right lower lobe and a portion of the right middle lobe. The specimen measures 110 mm medial to lateral x 120 mm superior to inferior x up to 120 mm anterior to posterior. Approximately 20 mm of middle lobe is present superior to the lower lobe and the interlobar fissure appears obliterated by adhesions. The main bronchus bifurcates 20 mm from the resection margin. The first branch runs horizontally towards the lateral surface and the second branch runs inferiorly. Immediately after the bifurcation the first horizontal bronchus is intimately involved with a large tumour mass. This tumour mass extends for 30 mm along the bronchus. Distal to this there is a large region of presumed carnification. This area involves the posterior basal and lateral basal segments and the apical segment. [Sections taken: BRM, 1A; two complete sections through bronchial tumour, 1B-1C; section of RML resection margin to include some carnification, 1D; section of lateral pleura with carnified lung, 1E; section of basal pleura with carnified lung, 1F; sections of hilar lymph nodes, 1G.]

Microscopy:

Sections show a poorly differentiated squamous cell carcinoma. The lesion is arising from a bronchus. In this region the bronchus shows squamous metaplasia with varying grades of dysplasia. Pleural invasion is not identified but tumour extends into hilar fat adjacent to the pulmonary artery. There is no blood vessel invasion but perineural permeation is identified. The lesion is well clear of the bronchial resection margin but there is tumour present in soft tissue adjacent to the pulmonary artery margin. Peribronchial lymph node metastases are seen and there is tumour within an extracapsular lymphatic supplying the node. The carnified distal lung shows prominent organising pneumonia with an associated granulomatous reaction.

2: LYMPH NODE NO. 7

Macroscopy:

The specimen is labelled "No. 7" and consists of a piece of tissue measuring 40 x 25 x 15 mm. On sectioning, this tissue is consistent with lymph node with marked anthracosis. [Complete section through the node taken, 1A-1B.] No focal lesions are identified.

[page 2 of 2]
[REDACTED]

Collected [REDACTED]

Histopathology Report

Microscopy:

Sections of the lymph node show reactive changes only. There is no evidence of malignancy.

Summary:

Right middle and lower lobes and lymph nodes:

- 1: Poorly differentiated squamous cell carcinoma; 30 mm in maximal dimension.
- 2: Perineural and lymphatic permeation identified; no blood vessel invasion present.
- 3: No pleural invasion identified; clear of bronchial margin but present adjacent to pulmonary artery margin.
- 4: Peribronchial lymph node metastases.
- 5: T1N1MX

[REDACTED]

Reported by [REDACTED]
Anatomical Pathologist
[REDACTED]

Copies: [REDACTED]

ADDENDUM REPORT

Some of the granulomatous inflammation distal to the lung carcinoma shows necrosis. No micro-organisms are identified with special stains (Gram, Grocott, PAS and Ziehl-Neelsen) and but a rare ferruginous body consistent with an asbestos body is noted.

Reported by [REDACTED]
Anatomical Pathologist
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file a2396c50-90ac-494b-8d26-66009398e2f6 (TCGA-77-8133.6DDD0CB2-FEA0-4B27-9468-CA4F085192D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).